Somatic mutation profile of tumor specimen TARGET-10-PAPGLS-09A (aliquot TARGET-10-PAPGLS-09A-01D) from TARGET case TARGET-10-PAPGLS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,592 days).
Specimen TARGET-10-PAPGLS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b16ce819-ca77-4fdd-83cb-7420b93f1114.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGLS-10A (Blood Derived Normal), aliquot TARGET-10-PAPGLS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31314568-2460-4890-890f-2ea2bde6239a

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Nonsense Mutation 2, 3'UTR 1, 3'Flank 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as rs774592932, COSV101663078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADRA2C | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.683); catalogued as rs369584534; called by muse, mutect2, varscan2
- ALDH2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773666853; called by muse, mutect2, varscan2
- CXCR1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs140728083; called by muse, mutect2, varscan2
- DDI1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765717385, COSV56369127; called by muse, mutect2, varscan2
- DPYSL5 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs144366814; called by muse, mutect2, varscan2
- FGFR4 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs148292303, COSV52801196, COSV52803650; called by muse, mutect2, varscan2
- PGK2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs780494411, COSV59162756, COSV59165503; called by muse, mutect2
- ROR2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.239); catalogued as rs1056691051, COSV65221658; called by muse, mutect2, varscan2
- RUSC2 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs991637509; called by muse, mutect2, varscan2
- SI | c.1802G>T p.W601L | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52272917; called by muse, mutect2, varscan2
- SLC12A1 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57712320; called by muse, mutect2, varscan2
- CDC14B | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- COL6A3 | c.4878C>A p.D1626E | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.3550G>T p.D1184Y (on ENST00000297405 / NM_001363185.1; = p.D1080Y on NM_052900.3) | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ITSN1 | c.4142G>T p.R1381L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A8 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPINT1 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- SYNRG | c.230T>G p.I77S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CENPJ | c.3633A>C p.A1211= | Silent (SNP) | VAF 45/163 reads (28%) | called by muse, mutect2, varscan2
- EGR1 | c.591C>T p.N197= | Silent (SNP) | VAF 68/206 reads (33%) | called by muse, mutect2, varscan2
- TMC7 | c.417G>A p.T139= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs549355789; called by muse, mutect2, varscan2
- ZNRF4 | c.342G>A p.A114= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs200517388; called by muse, mutect2, varscan2
- C1orf68 | c.*68G>T | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- IGKV1D-37 | chr2:89885216 ins GCA | 3'Flank (INS) | VAF 34/175 reads (19%) | called by mutect2, pindel, varscan2
- NCBP2L | chrX:107775076 ins CCGC | 5'Flank (INS) | VAF 18/28 reads (64%) | called by mutect2, varscan2
- NEBL | c.164+46367G>A | Intron (SNP) | VAF 24/176 reads (14%) | catalogued as rs377618156; called by muse, mutect2
